Somatic mutation profile of tumor specimen TCGA-CV-7245-01A (aliquot TCGA-CV-7245-01A-11D-2012-08) from TCGA case TCGA-CV-7245, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.0 years (22,646 days).
Specimen TCGA-CV-7245-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4185e2ff-c2dc-4131-8eb3-03f07e2d87df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7245-10A (Blood Derived Normal), aliquot TCGA-CV-7245-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8f32dd-f14f-4e6b-8d8a-5638490b7c32

The open-access MAF lists 552 somatic variants for this specimen: 409 protein-altering or splice-affecting, 124 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 358, Silent 124, Nonsense Mutation 27, Frame Shift Del 9, Splice Site 8, Intron 8, RNA 7, Translation Start Site 3, Frame Shift Ins 3, 5'UTR 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCED1B | c.1027T>C p.S343P | Missense Mutation (SNP) | VAF 13/251 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen possibly damaging (0.466); catalogued as COSV101423628; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 22/36 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VEGFC | c.362-2A>T p.X121_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as rs1057524647, COSV99709700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3281G>T p.G1094V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588603; called by muse, mutect2, varscan2
- AASDHPPT | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99593264; called by muse, mutect2, varscan2
- ABHD16B | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.649); catalogued as COSV99036775, COSV99410631; called by muse, mutect2, varscan2
- ABT1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1554144704, COSV99223187; called by muse, mutect2, varscan2
- ACAN | c.6872G>T p.G2291V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100717745; called by muse, varscan2
- ACO2 | c.1940C>G p.A647G | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.356); catalogued as COSV53443998, COSV99347278; called by muse, mutect2, varscan2
- ACTR1B | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as rs746639149, COSV56703147; called by muse, mutect2, varscan2
- ACVRL1 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as CM051000, COSV101187861; called by muse, mutect2, varscan2
- ADAM12 | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100900289; called by muse, mutect2, varscan2
- ADAM2 | c.267+2T>A p.X89_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99697154; called by muse, varscan2
- ADAMTS12 | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100710687, COSV61257213; called by muse, mutect2, varscan2
- ADGRE2 | c.1810G>C p.G604R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100215907; called by muse, mutect2, varscan2
- ADGRV1 | c.9542G>C p.G3181A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101315754, COSV67993555; called by muse, mutect2, varscan2
- ADHFE1 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99397754; called by muse, mutect2, varscan2
- ADNP | c.3091A>T p.S1031C | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as COSV100823704; called by muse, mutect2, varscan2
- AL592490.1 | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV101308145; called by muse, mutect2, varscan2
- ALG12 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | PolyPhen benign (0.048); catalogued as COSV100077966; called by muse, mutect2, varscan2
- ALPG | c.543C>A p.H181Q | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99779271; called by muse, mutect2, varscan2
- ALPP | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235131; called by muse, mutect2, varscan2
- AMOT | c.1535G>T p.R512I (on ENST00000371959 / NM_001113490.1; = p.R103I on NM_133265.3) | Missense Mutation (SNP) | VAF 98/184 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100494952; called by muse, mutect2, varscan2
- AMOTL1 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100133755; called by muse, mutect2, varscan2
- ANK2 | c.8465C>T p.T2822I | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100000960; called by muse, mutect2, varscan2
- ANKRD20A2P | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1379605519; called by mutect2, varscan2
- ANKRD30A | c.3715G>T p.V1239L (on ENST00000611781; = p.V1183L on NM_052997.2) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs777208649, COSV100653301; called by muse, varscan2
- ANXA11 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99627031; called by muse, mutect2, varscan2
- APBA1 | c.1507A>G p.R503G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs755857636, COSV99595875; called by muse, mutect2, varscan2
- APOL6 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs537732644, COSV101290982; called by muse, mutect2, varscan2
- AQP9 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 54/250 reads (22%) | catalogued as rs370192849, COSV54967386; called by muse, mutect2, varscan2
- ARHGAP20 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99503728, COSV99504729; called by muse, mutect2, varscan2
- ARHGAP25 | c.881+1G>T p.X294_splice (on ENST00000409202 / NM_001007231.3; = p.X286_splice on NM_014882.3) | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99771361; called by muse, mutect2, varscan2
- ARID5B | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99689474; called by muse, mutect2, varscan2
- ARRDC4 | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); catalogued as COSV99164349; called by muse, mutect2, varscan2
- ART1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs537517512, COSV99167151, COSV99167212; called by muse, mutect2, varscan2
- ATP10A | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100791100; called by muse, mutect2, varscan2
- ATP6V1C1 | c.161T>G p.L54W | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214945; called by muse, varscan2
- ATRNL1 | c.1190C>G p.T397R | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100744915; called by muse, mutect2, varscan2
- BFSP1 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749766370, COSV100925352; called by muse, mutect2, varscan2
- BLOC1S1 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV99221271; called by muse, mutect2, varscan2
- BNC2 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101032844; called by muse, mutect2, varscan2
- BOLL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377264153; called by muse, mutect2, varscan2
- BPIFA1 | c.263T>A p.L88H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100845635; called by muse, mutect2, varscan2
- BRCA1 | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV58787374; called by muse, mutect2, varscan2
- BRINP3 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.525); catalogued as COSV66519335; called by muse, mutect2, varscan2
- BRWD1 | c.4277A>G p.Q1426R | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.622); catalogued as COSV100313236; called by muse, mutect2, varscan2
- C12orf66 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100320663; called by muse, mutect2, varscan2
- C14orf39 | c.1682A>G p.Q561R | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100407471; called by muse, mutect2, varscan2
- C4A | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | catalogued as rs745686753, COSV101418325; called by muse, mutect2, varscan2
- C5orf38 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 44/229 reads (19%) | catalogued as COSV57410163; called by muse, mutect2, varscan2
- CA3 | c.44A>T p.H15L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV53411418, COSV99570645; called by muse, mutect2, varscan2
- CCDC170 | c.1618A>C p.K540Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99498339; called by muse, mutect2, varscan2
- CCDC180 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs752684891, COSV100826645; called by muse, mutect2, varscan2
- CCDC191 | c.1549A>C p.N517H | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99878138; called by muse, mutect2, varscan2
- CCR7 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs1364141913, COSV99878657; called by muse, mutect2, varscan2
- CD163 | c.2804C>G p.P935R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV100775796; called by muse, mutect2, varscan2
- CDC42BPB | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 53/143 reads (37%) | catalogued as COSV100775367; called by muse, mutect2, varscan2
- CDH4 | c.2554G>T p.A852S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64658317; called by muse, mutect2, varscan2
- CDK9 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs11554104, COSV64724406; called by muse, mutect2, varscan2
- CDKN2A | c.64del p.R22Gfs*4 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as CM1515139; called by mutect2, pindel, varscan2
- CELSR1 | c.8729G>A p.S2910N | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99417804; called by muse, mutect2, varscan2
- CEP126 | c.2636G>C p.C879S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV99680933; called by muse, mutect2, varscan2
- CFAP410 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.038); catalogued as COSV100297147; called by muse, mutect2, varscan2
- CHD6 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100498054; called by muse, mutect2
- CHL1 | c.171T>A p.C57* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99850826; called by muse, mutect2, varscan2
- CHL1 | c.2864T>A p.I955K (on ENST00000397491 / NM_001253387.1; = p.I971K on NM_006614.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV99850828; called by muse, mutect2, varscan2
- CLCN3 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1219530656, COSV100641575; called by muse, mutect2, varscan2
- CNDP1 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722270; called by muse, mutect2, varscan2
- CNGA2 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.343); catalogued as COSV100323577; called by muse, mutect2, varscan2
- CNTN1 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100751230; called by muse, mutect2, varscan2
- COL11A1 | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100616007; called by muse, mutect2, varscan2
- COL14A1 | c.3214-2A>T p.X1072_splice | Splice Site (SNP) | VAF 31/169 reads (18%) | catalogued as COSV99918797; called by muse, mutect2, varscan2
- CPXCR1 | c.884C>A p.S295* | Nonsense Mutation (SNP) | VAF 17/19 reads (89%) | catalogued as COSV99342114; called by muse, mutect2, varscan2
- CR2 | c.2214T>A p.F738L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100889600; called by muse, mutect2, varscan2
- CREB5 | c.898C>T p.H300Y (on ENST00000357727 / NM_182898.4; = p.H293Y on NM_004904.3) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV100744463; called by muse, mutect2, varscan2
- CRIM1 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV99753079; called by muse, mutect2, varscan2
- CRY2 | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101314574, COSV101314594; called by muse, mutect2, varscan2
- CSMD3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs759891256, COSV52159750, COSV99827270; called by muse, mutect2, varscan2
- CTNND2 | c.2054C>A p.A685E | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV100475052, COSV58893685; called by muse, mutect2, varscan2
- CTRB2 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as rs1247409944, COSV100274698; called by muse, mutect2, varscan2
- CXCR1 | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99826303; called by muse, mutect2, varscan2
- CYP2E1 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV99428917, COSV99429175; called by muse, mutect2, varscan2
- DAAM2 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV99225368; called by muse, mutect2
- DAPK1 | c.3944G>A p.R1315H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as rs368364961; called by muse, mutect2, varscan2
- DCLK2 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651781; called by muse, mutect2, varscan2
- DDX58 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV101152709; called by muse, mutect2, varscan2
- DGKI | c.2654A>G p.N885S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99933630; called by muse, mutect2, varscan2
- DHX38 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99194273; called by muse, mutect2, varscan2
- DIAPH2 | c.2636T>C p.F879S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100232288; called by muse, mutect2, varscan2
- DNAH17 | c.7844G>T p.R2615L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101102000; called by muse, mutect2, varscan2
- DNAH5 | c.7784C>A p.A2595D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99448324; called by muse, mutect2, varscan2
- DNAH5 | c.5846G>T p.C1949F | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99448325; called by muse, mutect2, varscan2
- DNAJC12 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99830567; called by muse, mutect2, varscan2
- DOP1A | c.5414A>G p.K1805R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99381614; called by muse, mutect2, varscan2
- DOP1B | c.5975A>G p.K1992R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101215251; called by muse, mutect2, varscan2
- DPEP1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs150374214, COSV99878247; called by muse, mutect2, varscan2
- DPP4 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100858812; called by muse, mutect2, varscan2
- DPP9 | c.563G>A p.R188Q (on ENST00000598800; = p.R217Q on NM_139159.5) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs756569406, COSV53590406; called by muse, mutect2, varscan2
- DQX1 | c.1011A>T p.Q337H | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101098924; called by muse, mutect2, varscan2
- DSP | c.6118A>G p.I2040V | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV101131236; called by muse, mutect2, varscan2
- DUSP4 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as rs1229264590, COSV99529771; called by muse, mutect2, varscan2
- DYNC1H1 | c.10586T>G p.F3529C | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100794760; called by muse, mutect2, varscan2
- DYNC1I1 | c.1416-1G>T p.X472_splice | Splice Site (SNP) | VAF 36/215 reads (17%) | catalogued as COSV100268086; called by muse, mutect2, varscan2
- EBF3 | c.1416C>A p.Y472* (on ENST00000355311 / NM_001375392.1; = p.Y463* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as COSV100799142; called by muse, mutect2, varscan2
- ECM1 | c.11C>G p.T4R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.378); catalogued as COSV100681872; called by muse, mutect2, varscan2
- EHMT2 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100977176; called by muse, mutect2, varscan2
- ELF1 | c.1204A>G p.R402G | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99522976; called by muse, mutect2, varscan2
- ELMO1 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100164052; called by muse, mutect2, varscan2
- EP400 | c.3274G>A p.A1092T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100200981, COSV57775847; called by muse, mutect2, varscan2
- EPAS1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs944708829, COSV99763104; called by muse, mutect2, varscan2
- EPB42 | c.263A>G p.K88R (on ENST00000441366 / NM_001114134.2; = p.K118R on NM_000119.3) | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100281911; called by muse, mutect2, varscan2
- ERBIN | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99396571, COSV99396909; called by muse, mutect2, varscan2
- EXOC6B | c.1495A>T p.N499Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV99723688; called by muse, mutect2, varscan2
- EYS | c.1661G>C p.C554S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1222907085, COSV100676256; called by muse, mutect2, varscan2
- FABP6 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101221209; called by muse, mutect2, varscan2
- FAM71A | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1345314098, COSV99674509; called by muse, mutect2, varscan2
- FGR | c.289A>T p.T97S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766542896, COSV100925807; called by muse, mutect2, varscan2
- FIGNL1 | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100794884; called by muse, mutect2, varscan2
- FLG | c.11493T>A p.H3831Q | Missense Mutation (SNP) | VAF 104/457 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.967); catalogued as COSV100911455; called by muse, mutect2, varscan2
- FMO2 | c.602T>G p.V201G | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV99269063; called by muse, mutect2, varscan2
- FMO3 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100882427; called by muse, mutect2, varscan2
- FSHR | c.1945A>T p.M649L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV100436938; called by muse, mutect2, varscan2
- GABRA1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195805; called by muse, varscan2
- GABRA6 | c.248dup p.R84Pfs*6 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | catalogued as rs755508078; called by mutect2, varscan2
- GABRP | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.041); catalogued as COSV99516709; called by muse, mutect2, varscan2
- GABRR2 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746937315, COSV101298911; called by muse, varscan2
- GALNTL6 | c.1235C>G p.T412R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV101560119, COSV101560222; called by muse, mutect2, varscan2
- GALR1 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100231782, COSV100232093; called by muse, mutect2, varscan2
- GART | c.2483C>T p.T828I | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as rs777656742, COSV101111370; called by muse, mutect2
- GATM | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.242); catalogued as rs774017569, COSV101188202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDPD5 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100409255; called by muse, mutect2, varscan2
- GDPGP1 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100292035; called by muse, mutect2, varscan2
- GJA8 | c.293A>T p.H98L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1410334, CM1411612, COSV99569288; called by muse, mutect2, varscan2
- GLYCTK | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99980742; called by muse, mutect2, varscan2
- GPR132 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 55/163 reads (34%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100317524; called by muse, mutect2, varscan2
- GPR20 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100897301; called by muse, varscan2
- GRIA4 | c.1034T>C p.M345T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99230576; called by muse, mutect2, varscan2
- GRIN2A | c.3116C>A p.A1039E | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100409365; called by muse, mutect2, varscan2
- GRM3 | c.273G>C p.L91F | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100862445; called by muse, mutect2, varscan2
- H2BC10 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV59952767, COSV59953351; called by muse, mutect2, varscan2
- HAS3 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV54706672; called by muse, mutect2, varscan2
- HEATR3 | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs757634608, COSV99589857; called by muse, mutect2, varscan2
- HGF | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99736504; called by muse, mutect2, varscan2
- HMHB1 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 36/114 reads (32%) | PolyPhen probably damaging (0.987); catalogued as rs1456161714, COSV99193138; called by muse, mutect2, varscan2
- HOMER3 | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99651020; called by muse, mutect2, varscan2
- HRC | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99417819; called by muse, mutect2, varscan2
- HVCN1 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as rs1212903988, COSV99657172; called by muse, mutect2, varscan2
- IBTK | c.2753G>C p.G918A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100090536; called by muse, mutect2, varscan2
- IFNG | c.343T>A p.F115I | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99971139; called by muse, mutect2, varscan2
- IGSF5 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV101012038; called by muse, mutect2, varscan2
- IK | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV101341773; called by muse, mutect2, varscan2
- INPP5D | c.2994G>C p.K998N (on ENST00000445964 / NM_001017915.3; = p.K997N on NM_005541.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100856693; called by muse, mutect2
- IQCH | c.2627T>G p.V876G | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100245652; called by muse, mutect2, varscan2
- IRS4 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV64534590, COSV64535101; called by muse, mutect2, varscan2
- ITCH | c.1224A>T p.Q408H (on ENST00000262650 / NM_001257137.3; = p.Q367H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99392303; called by muse, mutect2, varscan2
- ITK | c.1379T>A p.L460Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101439689; called by muse, mutect2, varscan2
- JAG1 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV99652706; called by muse, mutect2, varscan2
- JMJD1C | c.5123T>G p.L1708R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550412; called by muse, varscan2
- KCNJ15 | c.917A>T p.Y306F | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100154149; called by muse, mutect2, varscan2
- KIAA0895 | c.227A>G p.N76S (on ENST00000297063 / NM_001100425.2; = p.N25S on NM_015314.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV99766744; called by muse, mutect2, varscan2
- KIF20B | c.3227A>C p.H1076P (on ENST00000371728 / NM_001284259.2; = p.H1036P on NM_016195.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99589836; called by muse, mutect2, varscan2
- KIF21A | c.3457G>T p.A1153S (on ENST00000361418 / NM_001378440.1; = p.A1140S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100735393; called by muse, mutect2, varscan2
- KIF21A | c.3209A>C p.K1070T (on ENST00000361418 / NM_001378440.1; = p.K1057T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62779681; called by muse, mutect2, varscan2
- KIF26B | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101313832; called by muse, mutect2, varscan2
- KIF6 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99758327; called by muse, mutect2, varscan2
- KIR3DL2 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99551697, COSV99551959; called by muse, varscan2
- KIRREL2 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99383859; called by muse, mutect2, varscan2
- KLHDC7A | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV101272761; called by muse, mutect2, varscan2
- KRT85 | c.1074C>A p.C358* | Nonsense Mutation (SNP) | VAF 60/169 reads (36%) | catalogued as COSV57737564, COSV57738019; called by muse, mutect2, varscan2
- LAMA4 | c.1582G>A p.E528K (on ENST00000230538 / NM_001105206.3; = p.E521K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.127); catalogued as rs782385471, COSV100038155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB1 | c.2485G>T p.V829F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV99740480; called by muse, mutect2, varscan2
- LAT2 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs781859231, COSV99305773, COSV99305941; called by muse, mutect2, varscan2
- LDB2 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58769108; called by muse, mutect2, varscan2
- LDLRAD4 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100762078; called by muse, mutect2, varscan2
- LIG1 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99618796; called by muse, mutect2, varscan2
- LPAR4 | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.238); catalogued as COSV101425103; called by muse, mutect2, varscan2
- LRIF1 | c.1682C>A p.A561E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV100870826; called by muse, mutect2, varscan2
- LRIT1 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs750726561, COSV64513756; called by muse, mutect2, varscan2
- LRP1 | c.6118G>A p.G2040S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675477; called by muse, mutect2, varscan2
- LRP1B | c.6512C>A p.A2171D | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101255382, COSV67228796; called by muse, mutect2, varscan2
- LRP1B | c.536G>C p.S179T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV101255384, COSV101257553; called by muse, mutect2, varscan2
- LRRC34 | c.1064C>G p.A355G (on ENST00000446859 / NM_001172779.2; = p.A323G on NM_153353.5) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100336257, COSV57185534; called by muse, mutect2, varscan2
- LRRC37A3 | c.4801C>T p.L1601F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100140978; called by muse, mutect2, varscan2
- LRRCC1 | c.1756C>A p.Q586K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100835390; called by muse, mutect2, varscan2
- LRRIQ3 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as COSV100598666; called by muse, mutect2, varscan2
- LRRN1 | c.453C>G p.N151K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100076208; called by muse, mutect2, varscan2
- LRRTM1 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99702274; called by muse, mutect2, varscan2
- LRRTM3 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100791595; called by muse, mutect2, varscan2
- LSAMP | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100370044; called by muse, mutect2, varscan2
- LUZP2 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100419603; called by muse, mutect2, varscan2
- LZTS2 | c.1035C>A p.D345E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV100932146; called by muse, mutect2, varscan2
- MAD1L1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs757656094, COSV99765738; called by muse, mutect2, varscan2
- MAGEB4 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.328); catalogued as COSV100974923; called by muse, mutect2, varscan2
- MAGEL2 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV100045877; called by muse, mutect2, varscan2
- MAML1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV99483050; called by muse, mutect2, varscan2
- MAP3K1 | c.1574A>T p.Q525L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.321); catalogued as COSV101266571; called by muse, mutect2, varscan2
- MAP3K21 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779367692, COSV64043697; called by mutect2, varscan2
- MEGF10 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371078929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFN1 | c.2045A>T p.Q682L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99764377; called by muse, mutect2, varscan2
- MRGPRX2 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100316710; called by muse, mutect2, varscan2
- MRPS30 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | catalogued as rs549231581, COSV99138149; called by muse, mutect2, varscan2
- MRTFA | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs780407081, COSV62934588; called by muse, varscan2
- MSH4 | c.2567C>G p.S856* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV54208389, COSV99591327; called by muse, mutect2, varscan2
- MSH5 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100994822; called by muse, mutect2, varscan2
- MSN | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100814175; called by muse, mutect2, varscan2
- MTA1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV100495086; called by muse, mutect2, varscan2
- MTBP | c.988A>G p.N330D | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100012051; called by muse, mutect2, varscan2
- MUC16 | c.24878C>A p.S8293Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV67456614; called by muse, mutect2, varscan2
- MUC17 | c.2803C>A p.P935T | Missense Mutation (SNP) | VAF 135/706 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1187226408, COSV100072727, COSV60280117; called by muse, mutect2, varscan2
- MYH6 | c.3078G>T p.K1026N | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1244161023, COSV100676450; called by muse, mutect2, varscan2
- MYLK | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100658878; called by muse, mutect2, varscan2
- NCL | c.777_782del p.E259_D260del | In Frame Del (DEL) | VAF 29/102 reads (28%) | catalogued as rs770891540; called by mutect2, pindel, varscan2
- NDST3 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99630252; called by muse, mutect2, varscan2
- NDUFAF5 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100962092; called by muse, mutect2, varscan2
- NECTIN3 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100162332; called by muse, varscan2
- NECTIN3 | c.725G>T p.R242M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100162334; called by muse, varscan2
- NFRKB | c.296G>T p.R99L (on ENST00000446488 / NM_001143835.2; = p.R112L on NM_006165.3) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs749164897, COSV58757836, COSV58760583; called by muse, mutect2, varscan2
- NMI | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV99693341; called by muse, mutect2, varscan2
- NOD2 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.237); catalogued as COSV100318449; called by muse, mutect2, varscan2
- NOS1 | c.3772A>G p.I1258V | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV100500397; called by muse, mutect2, varscan2
- NPAP1 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100275170; called by muse, mutect2, varscan2
- NRDE2 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100583394; called by muse, mutect2, varscan2
- NRROS | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV100145449; called by muse, mutect2, varscan2
- NRXN1 | c.2523G>T p.R841S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100454442; called by muse, mutect2, varscan2
- NSD1 | c.4600G>T p.E1534* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as COSV100728805; called by muse, mutect2, varscan2
- NUDT18 | c.300T>A p.C100* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99248903; called by muse, mutect2
- NUDT7 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV99216042; called by muse, mutect2, varscan2
- OBSCN | c.19576G>T p.G6526W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100800333, COSV100803078; called by muse, mutect2, varscan2
- OR13C2 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101604866; called by muse, mutect2, varscan2
- OR4C12 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100078437; called by muse, mutect2, varscan2
- OR4C46 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as rs761413676, COSV100060896, COSV60218974; called by muse, mutect2, varscan2
- OR4L1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs369912800; called by muse, mutect2, varscan2
- OR56A4 | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs144089765, COSV100417535; called by muse, mutect2, varscan2
- OR5B3 | c.77T>C p.F26S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV100511964; called by muse, mutect2, varscan2
- OR5I1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1263873543, COSV100041356; called by muse, mutect2, varscan2
- OR5M1 | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); catalogued as COSV101591550; called by muse, mutect2, varscan2
- OVCH1 | c.1374A>G p.I458M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV100548450; called by muse, mutect2, varscan2
- PAX6 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99570334; called by muse, mutect2, varscan2
- PCDH19 | c.3160G>C p.E1054Q (on ENST00000373034 / NM_001184880.2; = p.E1006Q on NM_020766.3) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55258846, COSV99719541; called by muse, varscan2
- PCDHA6 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as rs1293242717, COSV100972223; called by muse, mutect2, varscan2
- PCDHB12 | c.739T>G p.Y247D | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53395503, COSV99507127; called by muse, mutect2, varscan2
- PCDHB12 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs532396499, COSV53398691, COSV99507128; called by muse, mutect2, varscan2
- PCDHB2 | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99164885; called by muse, mutect2, varscan2
- PCDHB8 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as rs782003552, COSV50754292; called by muse, mutect2
- PCLO | c.1448A>T p.Q483L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1263399290, COSV61633409; called by muse, mutect2, varscan2
- PGM5 | c.993G>C p.M331I | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV101123414; called by muse, mutect2
- PKD1L1 | c.4161G>C p.M1387I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99219265; called by muse, mutect2, varscan2
- PKHD1 | c.4063C>T p.P1355S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61870485; called by muse, mutect2, varscan2
- PLAA | c.826T>C p.C276R | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV101263507; called by muse, mutect2, varscan2
- PLAC8L1 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100268726; called by muse, mutect2, varscan2
- PLEC | c.8266C>A p.Q2756K (on ENST00000322810 / NM_201380.4; = p.Q2646K on NM_000445.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100512933; called by muse, mutect2, varscan2
- PLPPR2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.15); catalogued as rs990918432, COSV99264374; called by muse, mutect2, varscan2
- PLXNA4 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV100323755; called by muse, mutect2, varscan2
- PNPLA6 | c.4000A>T p.R1334W (on ENST00000414982 / NM_001166111.2; = p.R1286W on NM_006702.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99653510; called by muse, mutect2, varscan2
- PNPLA7 | c.3328G>T p.D1110Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99480473; called by muse, mutect2, varscan2
- POPDC3 | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99633617; called by muse, mutect2, varscan2
- PPIP5K2 | c.1533G>T p.W511C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100383718; called by muse, mutect2, varscan2
- PRDM9 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99690251; called by muse, mutect2, varscan2
- PREP | c.251G>T p.W84L (on ENST00000369110; = p.W150L on NM_002726.5) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64869638, COSV64872227; called by muse, mutect2, varscan2
- PREX1 | c.4673G>A p.G1558E | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100906189; called by muse, mutect2, varscan2
- PRTG | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66841166; called by muse, mutect2, varscan2
- PSMB11 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV57459655; called by muse, mutect2, varscan2
- PSME4 | c.2542G>T p.E848* | Nonsense Mutation (SNP) | VAF 102/219 reads (47%) | catalogued as COSV101122436; called by muse, mutect2, varscan2
- PTH2R | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as rs1201632076, COSV99782331; called by muse, mutect2, varscan2
- PTPN13 | c.7019C>G p.A2340G (on ENST00000411767 / NM_080683.3; = p.A2321G on NM_006264.3) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV100364562; called by muse, mutect2, varscan2
- PTPRF | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100740804; called by muse, mutect2, varscan2
- PTPRJ | c.2980A>G p.I994V | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101394873; called by muse, mutect2, varscan2
- RAB11B | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100033031; called by muse, mutect2, varscan2
- RAB7A | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99414006; called by muse, mutect2, varscan2
- RALGAPA1 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99354240; called by muse, mutect2, varscan2
- RANBP3L | c.1065C>A p.S355R | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99683731; called by muse, mutect2, varscan2
- RASGRP3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101274732; called by muse, mutect2, varscan2
- REG1A | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1254064793, COSV99286714; called by muse, mutect2, varscan2
- RELN | c.9725C>A p.T3242K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.178); catalogued as COSV100633320; called by muse, mutect2, varscan2
- REM1 | c.383C>A p.T128N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99147083; called by muse, mutect2, varscan2
- RGS9 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV99287347; called by muse, mutect2, varscan2
- RHBDD1 | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391580; called by muse, mutect2, varscan2
- RHOD | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747526322, COSV100448058; called by muse, mutect2, varscan2
- RINT1 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs751659106, COSV99994337; called by muse, mutect2, varscan2
- RNASE4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100489318; called by muse, mutect2, varscan2
- RNF148 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.417); catalogued as rs201395313; called by muse, mutect2, varscan2
- RNF150 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100153209; called by muse, mutect2
- RNF20 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.133); catalogued as COSV101206516; called by muse, mutect2, varscan2
- ROS1 | c.3634C>A p.R1212S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs780046038, COSV100876917; called by muse, mutect2, varscan2
- RP1 | c.1989G>T p.K663N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs372551375, CM992206, COSV99607074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.1197C>A p.N399K | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99173206; called by muse, mutect2, varscan2
- SASH3 | c.734G>C p.R245P | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.174); catalogued as COSV100795197; called by muse, mutect2, varscan2
- SCGN | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV100618702; called by muse, mutect2, varscan2
- SCN1A | c.3136G>C p.D1046H (on ENST00000303395 / NM_001202435.3; = p.D1035H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100320103; called by muse, mutect2, varscan2
- SCNN1G | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100264107, COSV55598494; called by muse, mutect2, varscan2
- SEL1L2 | c.1681C>A p.H561N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV99533001; called by mutect2, varscan2
- SEL1L2 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV53151532; called by muse, mutect2, varscan2
- SEMA3C | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99542749; called by muse, mutect2, varscan2
- SERPINA9 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100098263; called by muse, mutect2, varscan2
- SFMBT2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV100738814; called by muse, varscan2
- SH2D5 | c.101T>A p.F34Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100903823; called by muse, mutect2, varscan2
- SHOX2 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99905922; called by muse, varscan2
- SLC12A3 | c.110A>T p.Y37F | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.052); catalogued as COSV99344068; called by muse, mutect2
- SLC22A11 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100102273, COSV57253314; called by muse, mutect2, varscan2
- SLC22A12 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as rs1016187793, COSV60571739; called by muse, mutect2
- SLC35F4 | c.745C>T p.L249F (on ENST00000339762 / NM_001352015.2; = p.L213F on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as rs868501894, COSV100333734; called by muse, mutect2, varscan2
- SLC36A2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs768169962, COSV100079062; called by muse, mutect2, varscan2
- SLC6A11 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV99594371; called by muse, mutect2, varscan2
- SLC6A18 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99721960, COSV99722227; called by muse, mutect2, varscan2
- SLCO1C1 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858928; called by muse, mutect2, varscan2
- SLIT1 | c.1869C>A p.N623K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56583092; called by muse, mutect2, varscan2
- SLITRK4 | c.2006G>A p.R669K | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.059); catalogued as COSV100567279; called by muse, mutect2, varscan2
- SLK | c.1875G>T p.E625D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV100211680; called by muse, mutect2, varscan2
- SMYD3 | c.194G>T p.C65F (on ENST00000490107 / NM_001375962.1; = p.C6F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193875; called by muse, mutect2, varscan2
- SNAPC4 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100047098; called by muse, mutect2, varscan2
- SOS2 | c.3364C>G p.L1122V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99365870; called by muse, mutect2, varscan2
- SOX8 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.885); catalogued as rs1208140437, COSV99559208; called by muse, mutect2, varscan2
- SPATA16 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs762096024, COSV63528712; called by muse, mutect2, varscan2
- SPATA6 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100893812, COSV64061089; called by muse, mutect2, varscan2
- SPEF2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV56796178, COSV99213995; called by muse, mutect2
- SPTBN5 | c.4460C>T p.A1487V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100311177; called by muse, mutect2, varscan2
- SSH1 | c.2321A>G p.K774R | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100425447; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs1309506880, COSV100561739; called by muse, mutect2, varscan2
- STRADA | c.995C>T p.P332L (on ENST00000336174 / NM_001363786.1; = p.P295L on NM_153335.6) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99368516; called by muse, mutect2, varscan2
- STX4 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100572921; called by muse, mutect2, varscan2
- SYNE1 | c.26289C>A p.C8763* (on ENST00000367255 / NM_182961.4; = p.C8715* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV55016522; called by muse, mutect2, varscan2
- SYNE1 | c.25710C>A p.D8570E (on ENST00000367255 / NM_182961.4; = p.D8522E on NM_033071.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99560427; called by muse, mutect2, varscan2
- TAF4 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 122/637 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99433960; called by muse, mutect2, varscan2
- TAFA2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV101353170; called by muse, mutect2, varscan2
- TBX15 | c.387T>G p.I129M (on ENST00000369429 / NM_001330677.2; = p.I23M on NM_152380.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99253947; called by muse, mutect2, varscan2
- TDRD5 | c.1915A>G p.T639A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99676004; called by muse, mutect2, varscan2
- TECR | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99295063; called by muse, mutect2, varscan2
- TENM1 | c.3811G>T p.D1271Y | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100949737; called by muse, mutect2, varscan2
- TFRC | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100786443; called by muse, mutect2, varscan2
- TG | c.7331T>C p.M2444T | Missense Mutation (SNP) | VAF 134/250 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1323535588, COSV99600263; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51516762, COSV99304982; called by muse, mutect2, varscan2
- TGM4 | c.1897C>A p.Q633K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV99942244; called by muse, mutect2, varscan2
- THSD7A | c.2738C>A p.S913Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101448643; called by muse, mutect2, varscan2
- TMED10 | c.359A>C p.Q120P | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100339784; called by muse, mutect2, varscan2
- TMEM132B | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100169267; called by muse, mutect2, varscan2
- TMEM154 | c.392+1G>A p.X131_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as rs1486409825, COSV100433063; called by muse, mutect2, varscan2
- TMEM237 | c.636G>T p.W212C (on ENST00000409883 / NM_001044385.3; = p.W204C on NM_152388.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99635788; called by muse, mutect2, varscan2
- TMTC2 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs775487177, COSV100337774; called by muse, mutect2, varscan2
- TPH2 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1201344273, COSV100422014; called by muse, mutect2, varscan2
- TRAV30 | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs761659730; called by muse, mutect2, varscan2
- TRDN | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100521624, COSV100523289; called by muse, mutect2
- TREML2 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV101530167; called by muse, mutect2, varscan2
- TRHDE | c.1118C>G p.T373R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99670251; called by muse, mutect2, varscan2
- TRIM48 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101338255; called by muse, mutect2, varscan2
- TRPV5 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs781164328, COSV99520360; called by muse, mutect2, varscan2
- TST | c.847G>C p.A283P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1350179536, COSV50765262; called by muse, mutect2
- TTN | c.101359G>C p.D33787H (on ENST00000591111; = p.D26363H on NM_003319.4) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | PolyPhen probably damaging (0.998); catalogued as COSV100605609; called by muse, mutect2, varscan2
- TUT1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1020036162, COSV99545227; called by muse, mutect2, varscan2
- TWNK | c.1244-2A>T p.X415_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99272278; called by muse, mutect2, varscan2
- UBD | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100589618; called by muse, mutect2, varscan2
- UBN2 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1431392121, COSV99943835; called by muse, mutect2, varscan2
- UBXN7 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99581138; called by muse, mutect2, varscan2
- UGDH | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100328449; called by muse, mutect2, varscan2
- UGT2B4 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522349; called by muse, mutect2, varscan2
- UGT2B7 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.147); catalogued as rs960076700, COSV100535173; ClinVar: drug response; called by muse, mutect2, varscan2
- UNC79 | c.5407C>T p.P1803S (on ENST00000393151 / NM_001346218.2; = p.P1626S on NM_020818.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as COSV99827199; called by muse, mutect2, varscan2
- UNCX | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310234; called by muse, mutect2, varscan2
- USH2A | c.7881C>G p.I2627M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56378138; called by muse, mutect2, varscan2
- USP6 | c.2389G>A p.V797I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs751423143, COSV100003680; called by muse, mutect2, varscan2
- UTS2B | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100484163; called by muse, mutect2, varscan2
- VAT1L | c.883T>C p.W295R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213334; called by muse, mutect2, varscan2
- VCAM1 | c.1963A>G p.I655V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1377884568, COSV99658433; called by muse, mutect2, varscan2
- VEGFC | c.1223G>C p.C408S | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99709699; called by muse, mutect2, varscan2
- VEPH1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100747494; called by muse, mutect2, varscan2
- VIPR2 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056998; called by muse, mutect2, varscan2
- VN1R2 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV100447862; called by muse, mutect2
- WDFY3 | c.7142G>C p.R2381T | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99883044; called by muse, mutect2, varscan2
- WDFY3 | c.6763G>T p.E2255* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99883047; called by muse, mutect2, varscan2
- WDR24 | c.1144G>A p.A382T (on ENST00000248142; = p.A252T on NM_032259.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs145838196; called by muse, mutect2, varscan2
- WDR49 | c.2014A>C p.K672Q (on ENST00000308378 / NM_001366158.1; = p.K1013Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99247842; called by muse, mutect2, varscan2
- WDR49 | c.917T>A p.I306N (on ENST00000308378 / NM_001366158.1; = p.I647N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392349; called by muse, mutect2, varscan2
- XIRP2 | c.8863G>T p.A2955S (on ENST00000628543; = p.A3130S on NM_152381.6) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99741576; called by muse, mutect2, varscan2
- ZCWPW2 | c.834del p.Q278Hfs*21 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV101075405; called by mutect2, pindel, varscan2
- ZFAND4 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100762948; called by muse, mutect2, varscan2
- ZFP28 | c.2170A>G p.T724A | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs752026531, COSV100019490, COSV56736288; called by muse, mutect2, varscan2
- ZIC4 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs756694792, COSV67173294; called by muse, mutect2, varscan2
- ZNF133 | c.1454A>G p.Q485R (on ENST00000316358 / NM_001352454.2; = p.Q484R on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs544778156, COSV100315414; called by muse, mutect2, varscan2
- ZNF133 | c.1925C>T p.P642L (on ENST00000316358 / NM_001352454.2; = p.P641L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1332744771, COSV100315417, COSV60366167; called by muse, mutect2, varscan2
- ZNF184 | c.1967A>T p.H656L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV99279549; called by muse, mutect2, varscan2
- ZNF222 | c.783A>G p.I261M | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as rs771626053, COSV99496239; called by muse, mutect2, varscan2
- ZNF33B | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1179678327, COSV100847665; called by muse, mutect2, varscan2
- ZNF462 | c.4838C>T p.P1613L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.551); catalogued as rs550408928, COSV52936742, COSV99473700; called by muse, mutect2, varscan2
- ZNF518B | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV100456658; called by muse, mutect2, varscan2
- ZNF530 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); catalogued as COSV100252503, COSV60531229; called by muse, mutect2, varscan2
- ZNF587 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 64/162 reads (40%) | catalogued as COSV100299404; called by muse, mutect2, varscan2
- ZNF616 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.181); catalogued as COSV100348272; called by muse, mutect2, varscan2
- ZNF625 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100863474; called by muse, mutect2, varscan2
- ZNF625 | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs370418950, COSV63241332; called by muse, mutect2, varscan2
- ZNF670 | c.1098A>T p.E366D | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100829224; called by muse, mutect2, varscan2
- ZNF804A | c.2982T>A p.Y994* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as COSV100167377, COSV56449326; called by muse, mutect2, varscan2
- ZNF831 | c.4853C>G p.S1618C | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV100925956; called by muse, mutect2, varscan2
- ZNF883 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV101432553; called by muse, mutect2, varscan2
- AC134980.2 | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPJ | c.2651del p.G884Efs*6 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- CRISP3 | c.644dup p.Y216Lfs*2 (on ENST00000371159 / NM_001368123.1; = p.Y198Lfs*2 on NM_006061.4) | Frame Shift Ins (INS) | VAF 7/75 reads (9%) | called by mutect2, pindel
- ENTPD8 | c.1447_1456del p.V483Pfs*36 (on ENST00000371506 / NM_001033113.2; = p.V446Pfs*36 on NM_198585.3) | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- FBXL7 | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- HEATR9 | c.1349A>T p.Q450L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGKV2D-24 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- INSM1 | c.1415dup p.Y473Vfs*81 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- IQCJ-SCHIP1 | c.221del p.P74Hfs*9 | Frame Shift Del (DEL) | VAF 100/235 reads (43%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NUP155 | c.1583del p.V528Gfs*55 (on ENST00000231498 / NM_153485.3; = p.V469Gfs*55 on NM_004298.4) | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, pindel, varscan2
- PCDH19 | c.3107del p.K1036Rfs*6 (on ENST00000373034 / NM_001184880.2; = p.K988Rfs*6 on NM_020766.3) | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by pindel, varscan2
- SMTNL1 | c.1022del p.G341Vfs*14 (on ENST00000399154; = p.G378Vfs*14 on NM_001105565.2) | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- TRAV25 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRDV1 | c.269_270del p.A90Gfs*? | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- WASHC2A | c.2405G>A p.S802N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- ABHD17C | c.402G>T p.T134= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99358610; called by muse, mutect2
- ADNP2 | c.2859G>C p.P953= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100080740; called by muse, mutect2, varscan2
- AKAP9 | c.2223T>G p.L741= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100662273; called by muse, mutect2
- ANGEL1 | c.813C>T p.D271= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99200371; called by muse, mutect2, varscan2
- ANK3 | c.10029A>G p.Q3343= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs201376469; called by muse, mutect2, varscan2
- ATP8B1 | c.429C>T p.T143= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV99377150; called by muse, mutect2, varscan2
- BCL9L | c.2142G>T p.A714= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs770474642, COSV99419071; called by muse, mutect2, varscan2
- BCORL1 | c.2556G>T p.L852= | Silent (SNP) | VAF 88/118 reads (75%) | catalogued as COSV99499145; called by muse, mutect2, varscan2
- BDP1 | c.5937T>C p.N1979= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1328361461, COSV100702943; called by muse, mutect2, varscan2
- BECN1 | c.456C>G p.L152= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100831100; called by muse, mutect2, varscan2
- BRAF | c.1423A>C p.R475= (on ENST00000288602 / NM_001374244.1; = p.R435= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99958462; called by muse, mutect2, varscan2
- CASP4 | c.792G>T p.G264= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV101274132; called by muse, mutect2, varscan2
- CLEC1B | c.477C>A p.V159= | Silent (SNP) | VAF 83/541 reads (15%) | catalogued as COSV100046032; called by muse, mutect2, varscan2
- CLIP1 | c.1866A>T p.L622= (on ENST00000620786 / NM_001247997.1; = p.L611= on NM_002956.2) | Silent (SNP) | VAF 74/183 reads (40%) | catalogued as COSV100211539; called by muse, mutect2, varscan2
- COL12A1 | c.5733G>T p.V1911= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs777921160, COSV100485785; called by muse, mutect2, varscan2
- COL22A1 | c.1389A>T p.P463= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100277740; called by muse, mutect2, varscan2
- CPT1A | c.1692G>A p.T564= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1159341156, COSV55761829; called by muse, mutect2, varscan2
- CRYBB3 | c.396G>A p.V132= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99309030; called by muse, mutect2, varscan2
- CSMD3 | c.2661G>A p.L887= (on ENST00000297405 / NM_001363185.1; = p.L783= on NM_052900.3) | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs147640061, COSV99831345; called by muse, mutect2, varscan2
- CTNNAL1 | c.1224A>G p.L408= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs755522660, COSV100336471; called by muse, mutect2, varscan2
- CTNND2 | c.2055G>A p.A685= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs778345285; called by muse, mutect2, varscan2
- CTNND2 | c.1656G>T p.L552= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV100475056; called by muse, mutect2, varscan2
- CUL7 | c.2877G>C p.T959= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as COSV54821736, COSV99538370; called by muse, mutect2, varscan2
- DCAF12L2 | c.132G>A p.R44= | Silent (SNP) | VAF 49/52 reads (94%) | catalogued as COSV100758549; called by muse, mutect2, varscan2
- DHRS2 | c.117C>A p.A39= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV99158967; called by muse, mutect2, varscan2
- DLC1 | c.966G>A p.K322= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99362462; called by muse, mutect2, varscan2
- DZIP1L | c.1158C>T p.A386= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as COSV100551291; called by muse, mutect2, varscan2
- EIF2B5 | c.453G>A p.V151= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs376258328, CD051733; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ELAC2 | c.495G>T p.V165= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100568448, COSV100568503; called by muse, mutect2, varscan2
- EYA4 | c.1605A>T p.A535= (on ENST00000531901 / NM_001301013.1; = p.A529= on NM_004100.5) | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as COSV100765590; called by muse, mutect2, varscan2
- FANCE | c.909G>A p.E303= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV100003296; called by muse, mutect2, varscan2
- FBLN7 | c.870C>T p.T290= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs370641244; called by muse, mutect2, varscan2
- FUT9 | c.132C>A p.A44= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100133412; called by muse, mutect2, varscan2
- GALNT17 | c.555G>A p.K185= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100353455; called by muse, mutect2, varscan2
- GALNT8 | c.465C>T p.N155= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV99362717; called by muse, mutect2, varscan2
- GART | c.2485C>A p.R829= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV101111369, COSV67819251; called by muse, mutect2
- GLYR1 | c.1530C>A p.A510= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as COSV100424188; called by muse, varscan2
- GTF2F2 | c.276A>G p.T92= | Silent (SNP) | VAF 58/78 reads (74%) | catalogued as rs770682484, COSV100476757; called by muse, mutect2, varscan2
- HEATR5B | c.4434A>G p.P1478= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV99248984; called by muse, mutect2, varscan2
- HRNR | c.5466G>A p.Q1822= | Silent (SNP) | VAF 39/990 reads (4%) | called by muse, mutect2
- HSPA4L | c.1023A>T p.V341= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV99612855; called by muse, mutect2, varscan2
- HSPG2 | c.6624G>A p.V2208= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV101020623; called by muse, mutect2, varscan2
- INPP4A | c.660G>A p.L220= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1400004968, COSV99303307; called by muse, mutect2
- IPO7 | c.3048A>C p.G1016= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101121811; called by muse, mutect2, varscan2
- ITGB4 | c.2940C>T p.N980= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99563863; called by muse, mutect2, varscan2
- KCNA1 | c.1218C>T p.V406= | Silent (SNP) | VAF 181/507 reads (36%) | catalogued as COSV101230190; called by muse, mutect2, varscan2
- KCNJ3 | c.720G>A p.E240= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV54533753, COSV54534095; called by muse, mutect2, varscan2
- KEL | c.1605C>A p.S535= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100787012; called by muse, mutect2, varscan2
- KIF5A | c.2328C>A p.S776= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99672834; called by muse, mutect2, varscan2
- KLHL32 | c.1011C>T p.S337= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs1480834916, COSV100987229; called by muse, mutect2, varscan2
- LRP2 | c.11202T>C p.P3734= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV99787783; called by muse, mutect2, varscan2
- LRP5 | c.2109C>T p.F703= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99591788; called by muse, mutect2, varscan2
- LRRC4B | c.585G>T p.L195= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100975889; called by muse, mutect2, varscan2
- LRRN4 | c.2076C>A p.G692= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101125427; called by muse, mutect2
- LRRTM4 | c.1233T>A p.P411= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV101297510; called by muse, mutect2, varscan2
- M1AP | c.216G>A p.Q72= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV51848588; called by muse, mutect2, varscan2
- MDGA2 | c.1545T>A p.V515= (on ENST00000399232 / NM_001113498.2; = p.V217= on NM_182830.4) | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV100636833; called by muse, mutect2, varscan2
- MSGN1 | c.579G>A p.A193= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV99808723; called by muse, mutect2, varscan2
- MUC16 | c.16236A>G p.T5412= | Silent (SNP) | VAF 110/614 reads (18%) | catalogued as COSV101199398; called by muse, mutect2, varscan2
- MYC | c.1230G>A p.E410= (on ENST00000377970; = p.E425= on NM_002467.6) | Silent (SNP) | VAF 42/335 reads (13%) | catalogued as COSV99420069; called by muse, mutect2, varscan2
- MYOM2 | c.2229G>T p.L743= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100037313; called by muse, mutect2, varscan2
- NDST3 | c.102C>T p.Y34= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV99630248; called by muse, mutect2, varscan2
- NLRP11 | c.2721A>T p.R907= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100789706; called by muse, mutect2, varscan2
- NLRP3 | c.591C>T p.P197= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs3806267, COSV100275779, COSV100275989, COSV60220183; called by muse, mutect2, varscan2
- NRG3 | c.978C>A p.V326= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100931203; called by muse, mutect2, varscan2
- OR51B5 | c.570C>A p.T190= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as COSV56177066; called by muse, mutect2, varscan2
- OR52A1 | c.735T>C p.I245= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100200469; called by muse, mutect2, varscan2
- OR5I1 | c.498T>C p.F166= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV100041352; called by muse, mutect2, varscan2
- OR5M11 | c.882A>G p.K294= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV101602034; called by muse, mutect2, varscan2
- OR5T3 | c.471C>T p.I157= | Silent (SNP) | VAF 105/231 reads (45%) | catalogued as COSV100282765; called by muse, mutect2, varscan2
- OR8J1 | c.207T>C p.I69= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV100274957; called by muse, mutect2, varscan2
- PCDH15 | c.5355T>A p.G1785= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100903758; called by muse, mutect2, varscan2
- PCDHA3 | c.147G>T p.A49= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs1388952872, COSV100973785, COSV65366629; called by muse, mutect2, varscan2
- PDE3A | c.1347T>C p.G449= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV100762040; called by muse, mutect2, varscan2
- PIK3CG | c.705C>G p.V235= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV100782795; called by muse, mutect2, varscan2
- PKHD1L1 | c.10377T>A p.G3459= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV101005955; called by muse, mutect2, varscan2
- PLSCR4 | c.831G>A p.R277= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs1298159947, COSV100724177, COSV61608103; called by muse, mutect2
- POLR1B | c.1344A>G p.L448= | Silent (SNP) | VAF 68/308 reads (22%) | catalogued as rs758154850, COSV99637542; called by muse, mutect2, varscan2
- PRAMEF18 | c.318G>A p.R106= | Silent (SNP) | VAF 21/302 reads (7%) | called by muse, mutect2
- PTPRF | c.1731C>G p.L577= | Silent (SNP) | VAF 76/116 reads (66%) | catalogued as COSV100740805; called by muse, varscan2
- RAB41 | c.111G>T p.L37= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99333620; called by muse, mutect2, varscan2
- REC8 | c.36C>T p.T12= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100268971; called by muse, mutect2, varscan2
- RYR2 | c.6618A>T p.I2206= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV100769497; called by muse, mutect2, varscan2
- S100A7 | c.168C>A p.A56= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100906727; called by muse, mutect2, varscan2
- SCN10A | c.1617G>C p.L539= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs1483080379, COSV101479345; called by muse, mutect2, varscan2
- SEC24A | c.1923C>A p.L641= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100524439; called by muse, mutect2, varscan2
- SEPTIN3 | c.459C>T p.F153= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs779242157, COSV99352038; called by muse, mutect2, varscan2
- SERPINA11 | c.297C>A p.I99= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV100594004, COSV58241845; called by muse, mutect2, varscan2
- SF3B1 | c.3048G>C p.L1016= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100134401; called by muse, mutect2, varscan2
- SIGLEC1 | c.2901A>T p.S967= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99164023; called by muse, mutect2, varscan2
- SIGLEC1 | c.2322C>T p.C774= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV52465145; called by muse, mutect2, varscan2
- SLC12A3 | c.108C>T p.A36= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV99344066; called by muse, mutect2
- SLC22A1 | c.933G>A p.K311= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100266627; called by muse, mutect2, varscan2
- SLC25A23 | c.1320C>A p.P440= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99902135; called by muse, mutect2, varscan2
- SLCO6A1 | c.2040T>A p.T680= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101134225; called by muse, mutect2, varscan2
- SNTG1 | c.576G>T p.P192= | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as COSV52475114, COSV99383016; called by muse, mutect2, varscan2
- ST18 | c.2319C>T p.C773= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs369209561; called by muse, mutect2, varscan2
- ST3GAL4 | c.789G>C p.L263= (on ENST00000392669 / NM_001254758.1; = p.L259= on NM_006278.3) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99917395; called by muse, mutect2, varscan2
- TAS2R41 | c.222C>A p.V74= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV101281481; called by muse, varscan2
- TBC1D32 | c.2214A>T p.T738= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99250041; called by muse, mutect2, varscan2
- TFAP2B | c.777C>G p.P259= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99539959; called by muse, mutect2, varscan2
- THSD7A | c.649C>A p.R217= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV70264212; called by mutect2, varscan2
- TLR4 | c.1899C>T p.I633= (on ENST00000355622 / NM_138554.5; = p.I593= on NM_003266.4) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100842732; called by mutect2, varscan2
- TM9SF2 | c.970C>A p.R324= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100899695, COSV64507190; called by muse, mutect2, varscan2
- TNIK | c.3462G>A p.R1154= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV52679552, COSV99456588; called by muse, mutect2, varscan2
- TRIM71 | c.1314G>T p.L438= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as COSV101070412; called by muse, mutect2, varscan2
- TRPM8 | c.1221C>T p.A407= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV100223898; called by muse, mutect2, varscan2
- TRPV4 | c.1797G>T p.T599= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV55682635, COSV99924548; called by muse, mutect2, varscan2
- TTN | c.83733C>A p.T27911= (on ENST00000591111; = p.T20487= on NM_003319.4) | Silent (SNP) | VAF 64/152 reads (42%) | catalogued as COSV100605610; called by muse, mutect2, varscan2
- TTN | c.39558A>G p.L13186= (on ENST00000591111; = p.L5762= on NM_003319.4) | Silent (SNP) | VAF 126/224 reads (56%) | catalogued as COSV100605618; called by muse, mutect2, varscan2
- TTN | c.25599G>A p.E8533= (on ENST00000591111; = p.E7606= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs758738267, COSV100605622; called by muse, mutect2, varscan2
- TTN | c.10323T>C p.H3441= (on ENST00000591111; = p.H3395= on NM_003319.4) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs1376310602, COSV100605625; called by muse, mutect2, varscan2
- UNC5C | c.450G>T p.A150= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV101497865; called by muse, mutect2, varscan2
- UNC5C | c.27G>A p.A9= | Silent (SNP) | VAF 65/120 reads (54%) | catalogued as COSV71661986; called by muse, mutect2, varscan2
- VAV2 | c.2310G>T p.R770= (on ENST00000371850 / NM_001134398.2; = p.R760= on NM_003371.4) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100895687; called by muse, mutect2, varscan2
- VPS13D | c.10044G>T p.P3348= | Silent (SNP) | VAF 43/61 reads (70%) | catalogued as COSV99166135; called by muse, mutect2, varscan2
- VSX1 | c.831G>T p.G277= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV100942137; called by muse, mutect2, varscan2
- ZFP42 | c.66C>A p.P22= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100478784; called by muse, mutect2, varscan2
- ZFP90 | c.42G>A p.V14= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV101238749; called by muse, mutect2, varscan2
- ZMIZ1 | c.603G>C p.A201= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV100566045, COSV57899805; called by muse, mutect2
- ZNF462 | c.1629G>C p.P543= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99471440; called by muse, mutect2, varscan2
- ZNF536 | c.927T>A p.A309= | Silent (SNP) | VAF 96/223 reads (43%) | catalogued as COSV100835054; called by muse, mutect2, varscan2
- ZNF804A | c.1230T>A p.T410= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV100167376; called by muse, mutect2, varscan2
- ZPLD1 | c.1212A>G p.L404= (on ENST00000466937 / NM_001329788.1; = p.L420= on NM_175056.2) | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV100083112; called by muse, mutect2, varscan2
- AC024940.1 | n.2783G>A | RNA (SNP) | VAF 75/192 reads (39%) | catalogued as rs1414031252; called by muse, mutect2, varscan2
- CEP112 | c.2394+25584A>G | Intron (SNP) | VAF 80/316 reads (25%) | catalogued as rs1437257240, COSV100439083, COSV58062793; called by muse, mutect2, varscan2
- COL5A1 | c.654+7250A>G | Intron (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100879766; called by muse, mutect2, varscan2
- CXCL12 | c.266+2613G>C | Intron (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100638911, COSV59108261; called by muse, mutect2
- DCHS2 | n.4832C>A | RNA (SNP) | VAF 38/70 reads (54%) | catalogued as COSV100601564; called by muse, mutect2, varscan2
- DCHS2 | n.4017T>C | RNA (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100601566; called by muse, mutect2, varscan2
- MARCHF1 | c.163-16T>C | Intron (SNP) | VAF 51/88 reads (58%) | catalogued as COSV99920635; called by muse, mutect2, varscan2
- NRG2 | c.701-16840C>G | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56828715, COSV99180047; called by muse, mutect2, varscan2
- OR2U1P | n.549C>A | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.530+42G>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as COSV101188844; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163975 G>T | 5'Flank (SNP) | VAF 14/115 reads (12%) | called by mutect2, varscan2
- SNORD113-4 | n.3G>A | RNA (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- SNORD114-5 | n.16C>T | RNA (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- SNORD116-18 | n.20T>C | RNA (SNP) | VAF 63/150 reads (42%) | catalogued as rs775457346; called by muse, mutect2, varscan2
- SNRPG | c.-2C>T | 5'UTR (SNP) | VAF 27/132 reads (20%) | catalogued as rs775954821, COSV99231918; called by muse, mutect2, varscan2
- TTC8 | c.115-5755C>G | Intron (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100581255; called by muse, mutect2, varscan2
- TTN | c.10360+5155G>T | Intron (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100605624; called by muse, mutect2, varscan2
- VPS11 | c.-489C>G | 5'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs782680882, COSV100333675, COSV56187187; called by muse, mutect2, varscan2
- ZNF568 | c.*1A>T | 3'UTR (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100451245; called by muse, mutect2, varscan2
